Surgical pathology report (de-identified scan), TCGA case TCGA-BR-7196, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-7196-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Case ID	Subject ID	Gross Description	Microscopic Description	Diagnosis Details
[REDACTED]	[REDACTED]	Stomach segment with the plate-like tumor of 8.4 cm in size; whole wall is invaded. Greater and lesser curvature lymph nodes are dense, hyperemic; omentum -- hyperemia.	Adenocarcinoma of the stomach, G3; with perigastric fat invasion, foci of perineural invasion. Fifteen lymph nodes were dissected, eleven lymph nodes demonstrated metastases. Omentum demonstrates metastases, focal lymphoid infiltration, mesothelium proliferation.	

[page 2 of 2]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Subtotal gastrectomy Tumor site: Stomach Tumor size: 8.4 x 0 x 0 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Subserosa Lymph nodes: 11/15 positive for metastasis (Greater and lesser omentum 11/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

Lateralit y	Date of Procurement
NA	

Source: NCI Genomic Data Commons file 1fb7993f-3160-462c-a739-189b968d41e4 (TCGA-BR-7196.AE72546E-9A93-485C-9F00-F1495A64EC4C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).